Somatic mutation profile of tumor specimen TCGA-QR-A6GZ-01A (aliquot TCGA-QR-A6GZ-01A-11D-A35D-08) from TCGA case TCGA-QR-A6GZ, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 31.7 years (11,573 days).
Specimen TCGA-QR-A6GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77b82367-bd2b-4c1e-b429-83319135a25f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A6GZ-10A (Blood Derived Normal), aliquot TCGA-QR-A6GZ-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e96a54d-3c52-4b21-9a2a-c2fa740afd8c

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH20 | c.2011G>A p.G671S | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs928327481, COSV53017874; called by muse, mutect2, varscan2
- GBP6 | c.1018del p.Q340Sfs*3 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, varscan2
- GULP1 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2
- SALL1 | c.3092G>A p.C1031Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPCN1 | c.1031A>G p.H344R | Missense Mutation (SNP) | VAF 69/248 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- EPHB2 | c.2463C>T p.S821= (on ENST00000400191 / NM_001309193.2; = p.S822= on NM_004442.7) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV65867328; called by muse, mutect2, varscan2
